Surgical pathology report (de-identified scan), TCGA case TCGA-VP-A872, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Washington University, specimen TCGA-VP-A872-01A (Primary Tumor).

[page 1 of 4]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

ICD-O-3
Adenocarcinoma, acinar &
duct 8500/3
Site Prostate NOS
C61.9
QX 11/21/13

SURGICAL PATHOLOGY REPORT FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Service: Urology

Accession #: [REDACTED]

Location:

Taker:

Gender: M

MRN: [REDACTED]

Received:

DOB:

Hospital #: [REDACTED]

Accessioned:

Patient Type

Reported:

Physician(s):

Other Related Clinical Data:

DIAGNOSIS:

LYMPH NODE, BILATERAL PELVIC, DISSECTION

- NO EVIDENCE OF MALIGNANCY IN TWELVE LYMPH NODES (0/12)

PROSTATE, RADICAL PROSTATECTOMY

- ADENOCARCINOMA, MIXED ACINAR AND DUCTAL TYPES, WITH FOCAL FOAMY GLAND

FEATURES AND COMEDO NECROSIS, GLEASON GRADE 5+3 (=8)

- TUMOR INVOLVING BOTH LEFT AND RIGHT LOBES

- TUMOR FOCALLY EXTENDING INTO EXTRAPROSTATIC SOFT TISSUE

- BLADDER NECK, URETHRAL AND INKED PERIPHERAL SOFT TISSUE MARGINS FREE OF TUMOR

- SEMINAL VESICLES FREE OF TUMOR

- SEE COMMENT AND SYNOPSIS

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation:

"Called to pick up 'prostate' consisting of a 48 gm, 5 x 5 x 3 cm prostate with attached bilateral seminal vesicles. Tissue from left and right lobes taken for tumor bank. Rest for permanents," by

Microscopic Description and Comment:

Sections show extensive involvement of the prostate gland by mixed ductal and acinar adenocarcinoma with greater than 50% of the tumor showing ductal morphology. The ductal component exhibits abundant comedo-type necrosis (Gleason grade 5). The acinar component is mainly Gleason grade 3, but a tertiary pattern of Gleason 4 is also noted. We also see foamy gland features within the acinar component. [REDACTED] has reviewed this case and concurs.

[page 2 of 4]
Patient Name: [REDACTED]

History:

The patient is a [REDACTED] man with prostate cancer. Operative procedure:
Laparoscopic prostatectomy.

Specimen(s) Received:

A: LYMPH NODE, BILATERAL PELVIC

B: PROSTATE

Gross Description

The specimens are received in two formalin-filled containers, each labeled [REDACTED]. The first container is labeled "Pelvic lymph nodes." It consists of multiple fragments of adipose tissue measuring 5 x 4 x 1.2 cm. There are multiple lymph nodes extracted, the largest measures 2 x 0.8 x 0.5 cm; the smallest is 0.1 x 0.1 x 0.1 cm. Labeled A1 and A2 - dissected putative lymph nodes. Jar 1.

The second container is labeled "prostate." It consists of a single previously inked prostate weighing 48 gm and measuring 5 x 3 x 3 cm. The outer surface of the prostate is rough and was previously inked black. The right seminal vesicle measures 2.8 x 1.2 x 0.7 cm; the left seminal vesicle measures 3 x 1.2 x 0.6 cm. The right vas deferens measures 0.8 x 0.4 cm; the left vas deferens measures 1.5 x 0.5 cm. Serial sectioning shows tan nodular area on the urethra. The largest measures 0.5 x 0.8 cm. Also at the right apex are golden discolorations/nodular area, the largest measuring 0.2 x 0.2cm. Labeled B1 - right neck shave margin; B2 - left neck shave margin; B3 and B4 - right apical margin; B5 and B6 - left apical margin; B7 and B8 - right base; B9 and B10 - right apex; B11 and B12 - left base; B13 and B14 - left apex; B15 - right seminal vesicle; B16 - left seminal vesicle. Jar 2.

SYNOPTIC WORKSHEET - PROSTATE CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

The tumor type is adenocarcinoma, mixed ductal and acinar type

INTRAGLANDULAR TUMOR EXTENT

The intraglandular tumor extent (reported as percent of prostate gland involved by carcinoma) = >75%

GLEASON'S GRADE

The Gleason's Grade is 5+3=8

TUMOR LOCATION

The location of the tumor involves the
right base
right apex
left base
left apex

PERINEURAL INVASION

Perineural Invasion is identified

VASCULAR INVASION

Vascular Invasion is not identified

[page 3 of 4]
Patient Name: [REDACTED]

EXTRAPROSTATIC EXTENSION

Extraprostatic (extracapsular) extension is present

SEMINAL VESICLES

Seminal vesicles are free of tumor

SAMPLED SPECIMEN MARGINS

All sampled surgical margins are free of tumor

NON-NEOPLASTIC PROSTATE

The non-neoplastic prostate shows PIN, high grade, focal

METASTATIC LYMPH NODES

The lymph nodes are as follows (expressed as the number of metastatic nodes in relation to the total number of nodes examined)

Bilateral pelvic: (0/12)

PRIMARY TUMOR (T)

Extracapsular extension (unilateral or bilateral) (T3a)

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis (N0)

DISTANT METASTASIS

Distant metastasis cannot be assessed (not evaluated by any modality)

STAGE GROUPING

Based on this information, the overall AJCC/UICC stage of the tumor is T3/N0/M0/Gleason score 5+3 (Stage III)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica) _____ Completed Date: _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Gleason score on the initial pathology report is 5+3=8	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Top slide review Gleason score is 3+3=6	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The top slide review showed a different Gleason score from the Gleason score on the initial Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Rev _____

Director _____

Date _____

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Signature

Date

Source: NCI Genomic Data Commons file be28c88f-7ae4-4417-a983-493a55964af2 (TCGA-VP-A872.3B27B1E2-C41E-4D31-83F5-78882BDBB284.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).